Somatic mutation profile of tumor specimen MMRF_1995_2_BM_CD138pos (aliquot MMRF_1995_2_BM_CD138pos_T1_KHS5U_L15709) from MMRF case MMRF_1995, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.6 years (26,526 days).
Specimen MMRF_1995_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e64292a-fbce-4029-ba4b-07c98420f713.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1995_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1995_1_PB_WBC_C2_KHS5U_L08119; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acb0af82-5479-4caf-86bd-009592800739

The open-access MAF lists 199 somatic variants for this specimen: 72 protein-altering or splice-affecting, 25 silent, 102 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, 3'UTR 51, Silent 25, Intron 22, 5'UTR 12, 3'Flank 8, Nonsense Mutation 7, 5'Flank 5, RNA 4, Frame Shift Del 4, Frame Shift Ins 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 50/127 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.465dup p.T156Yfs*6 | Frame Shift Ins (INS) | VAF 16/40 reads (40%) | catalogued as rs1180724229; called by mutect2, varscan2
- ADGRV1 | c.10311G>T p.W3437C | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV101316426; called by muse, mutect2, varscan2
- AGO4 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs545951478, COSV64616360; called by muse, mutect2, varscan2
- ANXA10 | c.286C>T p.H96Y | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.992); catalogued as rs1248658830; called by muse, mutect2, varscan2
- BARX1 | c.107C>T p.T36M | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs1201657492; called by muse, mutect2
- CACHD1 | c.1523T>C p.F508S | Missense Mutation (SNP) | VAF 98/221 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV51558022; called by muse, mutect2, varscan2
- CACNB2 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as rs1422197851; called by muse, mutect2, varscan2
- CCDC74B | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs147577700, COSV100134805; called by muse, mutect2, varscan2
- CD177 | c.1175C>T p.A392V | Missense Mutation (SNP) | VAF 84/523 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs541810499, COSV100946081; called by muse, mutect2, varscan2
- CHST13 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1231021325, COSV60043121; called by muse, mutect2, varscan2
- CPSF1 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs782090510, COSV62938935; called by muse, mutect2, varscan2
- DNAH3 | c.3370A>C p.M1124L | Missense Mutation (SNP) | VAF 63/157 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV99770788; called by muse, mutect2, varscan2
- DUSP2 | c.659A>G p.K220R | Missense Mutation (SNP) | VAF 106/288 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1307944043; called by muse, varscan2
- IGHV2-70 | c.237C>A p.Y79* | Nonsense Mutation (SNP) | VAF 72/188 reads (38%) | catalogued as rs61733526; called by muse, varscan2
- IGLV3-1 | c.133A>C p.K45Q | Missense Mutation (SNP) | VAF 88/190 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs187892119; called by muse, varscan2
- KCNG1 | c.640C>A p.R214S | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.491); catalogued as COSV65368374; called by muse, mutect2
- KCNG2 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 4/65 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60267864; called by muse, mutect2
- MAGEA10 | c.157C>G p.P53A | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as COSV54882680; called by muse, mutect2, varscan2
- METTL27 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 9/82 reads (11%) | catalogued as COSV99936434; called by muse, mutect2, varscan2
- MYO15A | c.5900G>A p.R1967H | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs780235460; called by muse, mutect2, varscan2
- NPAP1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.101); catalogued as rs759520625, COSV100274550; called by muse, mutect2, varscan2
- NUP210L | c.3073A>C p.K1025Q | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as rs751685912; called by muse, mutect2, varscan2
- OTOG | c.8057C>T p.P2686L | Missense Mutation (SNP) | VAF 42/159 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs761369572; called by muse, mutect2, varscan2
- PAPSS1 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99491964; called by muse, mutect2, varscan2
- PCDHB15 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 66/244 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.012); catalogued as rs1554291881, COSV50912977; called by muse, mutect2, varscan2
- PIGR | c.754T>G p.S252A | Missense Mutation (SNP) | VAF 77/169 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.972); catalogued as rs1375768707; called by muse, mutect2, varscan2
- PIGZ | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 27/163 reads (17%) | catalogued as rs779107630, COSV53013643; called by muse, mutect2, varscan2
- PPFIA3 | c.3107G>A p.R1036Q | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs759215269, COSV53256908; called by muse, mutect2, varscan2
- SCRIB | c.2138A>G p.N713S | Missense Mutation (SNP) | VAF 72/188 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as rs782321933; called by muse, mutect2, varscan2
- SEC31A | c.1384dup p.I462Nfs*2 | Frame Shift Ins (INS) | VAF 60/166 reads (36%) | catalogued as rs748463349; called by mutect2, varscan2
- SLC15A3 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 43/196 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763376655, COSV99135634; called by muse, mutect2, varscan2
- SORBS3 | c.350G>T p.R117L | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs775027920; called by muse, mutect2, varscan2
- TEAD1 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV57566417; called by muse, mutect2, varscan2
- UACA | c.232A>G p.K78E | Missense Mutation (SNP) | VAF 71/228 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748426431; called by muse, mutect2, varscan2
- ACTG1 | c.92T>G p.F31C | Missense Mutation (SNP) | VAF 96/228 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ANKRD30A | c.3396del p.F1133Lfs*7 (on ENST00000611781; = p.F1077Lfs*7 on NM_052997.2) | Frame Shift Del (DEL) | VAF 88/248 reads (35%) | called by mutect2, pindel, varscan2
- ANKRD46 | c.538C>T p.R180* | Nonsense Mutation (SNP) | VAF 48/123 reads (39%) | called by muse, mutect2, varscan2
- ANXA13 | c.428A>C p.D143A | Missense Mutation (SNP) | VAF 75/162 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- APLF | c.1366G>C p.V456L | Missense Mutation (SNP) | VAF 82/200 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ASXL1 | c.2087T>C p.L696P | Missense Mutation (SNP) | VAF 105/283 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATCAY | c.821C>T p.S274L | Missense Mutation (SNP) | VAF 88/378 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- BAAT | c.76C>G p.P26A | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- CAPZB | c.456C>G p.H152Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- CHD5 | c.5017G>A p.E1673K | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- CXADR | c.656G>C p.G219A | Missense Mutation (SNP) | VAF 60/115 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLG1 | c.2624A>T p.D875V (on ENST00000419354 / NM_001290983.1; = p.D897V on NM_004087.2) | Missense Mutation (SNP) | VAF 76/330 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- FYCO1 | c.3313T>A p.Y1105N | Missense Mutation (SNP) | VAF 124/189 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- GLCCI1 | c.675dup p.S226Efs*3 | Frame Shift Ins (INS) | VAF 46/213 reads (22%) | called by mutect2, pindel, varscan2
- GNGT2 | c.77G>C p.R26T | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HACE1 | c.839T>A p.L280* | Nonsense Mutation (SNP) | VAF 51/200 reads (26%) | called by muse, mutect2, varscan2
- HERC2 | c.1870+2T>A p.X624_splice | Splice Site (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- IDO1 | c.317A>T p.N106I | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); called by muse, varscan2
- IGHV3-66 | c.317C>A p.A106D | Missense Mutation (SNP) | VAF 7/191 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.134); called by muse, mutect2
- ISL1 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 52/190 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MATK | c.1180G>T p.E394* (on ENST00000310132 / NM_139355.3; = p.E395* on NM_002378.4) | Nonsense Mutation (SNP) | VAF 31/95 reads (33%) | called by muse, mutect2, varscan2
- MGAM | c.5384A>T p.K1795I | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MIA3 | c.1776A>C p.R592S | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MORC1 | c.2644_2645del p.K882Efs*9 | Frame Shift Del (DEL) | VAF 21/98 reads (21%) | called by mutect2, pindel, varscan2
- MUC2 | c.1681C>T p.H561Y | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.03); called by muse, mutect2, varscan2
- NR3C1 | c.383A>G p.N128S | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.005); called by muse, varscan2
- PRKACA | c.638G>A p.S213N | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RANBP3 | c.1039G>C p.E347Q (on ENST00000340578 / NM_007322.3; = p.E342Q on NM_003624.3) | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); called by muse, mutect2
- RBM24 | c.530C>A p.P177H (on ENST00000379052 / NM_001143942.2; = p.P132H on NM_153020.2) | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- RFPL4B | c.419G>A p.C140Y | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- SP140 | c.1312_1318del p.Y438Mfs*71 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | called by mutect2, pindel, varscan2
- SYNE1 | c.1432C>G p.P478A (on ENST00000367255 / NM_182961.4; = p.P485A on NM_033071.3) | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- TFE3 | c.569_583del p.H190_A194del | In Frame Del (DEL) | VAF 37/47 reads (79%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.5009T>G p.L1670* | Nonsense Mutation (SNP) | VAF 86/240 reads (36%) | called by muse, varscan2
- ZNF462 | c.3412C>T p.P1138S | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF559 | c.1206_1207del p.H403Sfs*7 | Frame Shift Del (DEL) | VAF 79/336 reads (24%) | called by mutect2, pindel, varscan2
- ZNF768 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ACO1 | c.114G>A p.S38= | Silent (SNP) | VAF 48/179 reads (27%) | catalogued as rs754861122; called by muse, mutect2, varscan2
- ACTG1 | c.93T>C p.F31= | Silent (SNP) | VAF 97/230 reads (42%) | catalogued as rs1568063103; called by muse, mutect2, varscan2
- ASB17 | c.844C>T p.L282= | Silent (SNP) | VAF 66/176 reads (38%) | catalogued as COSV52411198; called by muse, mutect2, varscan2
- B4GALT7 | c.772C>T p.L258= | Silent (SNP) | VAF 64/239 reads (27%) | catalogued as rs1174249047; called by muse, mutect2, varscan2
- BTK | c.1113C>T p.S371= | Silent (SNP) | VAF 42/49 reads (86%) | called by muse, mutect2, varscan2
- CACNA1H | c.3531C>T p.D1177= | Silent (SNP) | VAF 77/230 reads (33%) | catalogued as rs954264851; called by muse, mutect2, varscan2
- CCNL2 | c.213C>T p.T71= | Silent (SNP) | VAF 46/180 reads (26%) | catalogued as rs766026340; called by muse, mutect2, varscan2
- DCLK3 | c.192C>T p.S64= | Silent (SNP) | VAF 80/274 reads (29%) | catalogued as rs373096178; called by muse, mutect2, varscan2
- ESRP1 | c.456T>C p.D152= | Silent (SNP) | VAF 126/316 reads (40%) | called by muse, mutect2, varscan2
- HOOK2 | c.1755C>T p.N585= | Silent (SNP) | VAF 21/170 reads (12%) | called by muse, mutect2, varscan2
- IGKC | c.318G>A p.E106= | Silent (SNP) | VAF 60/75 reads (80%) | catalogued as rs1028593629; called by muse, mutect2, varscan2
- KCNG3 | c.441G>A p.A147= | Silent (SNP) | VAF 32/76 reads (42%) | called by muse, mutect2, varscan2
- KLHL31 | c.1056A>C p.P352= | Silent (SNP) | VAF 136/292 reads (47%) | called by muse, mutect2, varscan2
- MAP2K1 | c.360G>A p.E120= | Silent (SNP) | VAF 47/123 reads (38%) | called by muse, mutect2, varscan2
- MSANTD1 | c.427C>T p.L143= | Silent (SNP) | VAF 59/139 reads (42%) | called by muse, mutect2, varscan2
- NABP1 | c.33A>T p.I11= | Silent (SNP) | VAF 24/76 reads (32%) | called by muse, mutect2, varscan2
- NKX2-5 | c.825C>T p.P275= | Silent (SNP) | VAF 52/162 reads (32%) | called by muse, mutect2, varscan2
- P3H4 | c.175C>T p.L59= | Silent (SNP) | VAF 64/138 reads (46%) | catalogued as rs782011053; called by muse, mutect2, varscan2
- PCDHA6 | c.1863G>A p.P621= | Silent (SNP) | VAF 9/183 reads (5%) | catalogued as rs782199993, COSV65343457; called by muse, mutect2
- SAFB2 | c.1425A>G p.G475= | Silent (SNP) | VAF 79/214 reads (37%) | called by muse, mutect2, varscan2
- SPATA5 | c.1119C>T p.L373= | Silent (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- TMEM235 | c.357G>A p.L119= | Silent (SNP) | VAF 69/161 reads (43%) | called by muse, mutect2, varscan2
- TSPOAP1 | c.2262C>T p.S754= | Silent (SNP) | VAF 46/108 reads (43%) | catalogued as rs775210061, COSV99271170; called by muse, mutect2, varscan2
- ZNF257 | c.756T>C p.T252= | Silent (SNP) | VAF 74/220 reads (34%) | called by muse, mutect2, varscan2
- ZSCAN10 | c.351T>C p.P117= (on ENST00000252463; = p.P172= on NM_032805.3) | Silent (SNP) | VAF 45/110 reads (41%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.*2588T>A | 3'UTR (SNP) | VAF 5/53 reads (9%) | catalogued as rs1295191308; called by muse, mutect2
- ADAR | c.*1587C>T | 3'UTR (SNP) | VAF 46/134 reads (34%) | called by muse, mutect2, varscan2
- ALDH1A3 | chr15:100877839 C>T | 5'Flank (SNP) | VAF 22/212 reads (10%) | catalogued as rs1233574527; called by muse, mutect2
- AR | c.*1238G>T | 3'UTR (SNP) | VAF 59/70 reads (84%) | catalogued as rs1465756888; called by muse, mutect2, varscan2
- ARHGAP26 | c.*5382del | 3'UTR (DEL) | VAF 70/141 reads (50%) | called by mutect2, pindel, varscan2
- ARHGEF16 | c.589-63A>G | Intron (SNP) | VAF 13/102 reads (13%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130914089 C>T | 5'Flank (SNP) | VAF 111/306 reads (36%) | catalogued as rs1212603450; called by muse, mutect2, varscan2
- ARRB1 | c.*976C>T | 3'UTR (SNP) | VAF 134/216 reads (62%) | catalogued as rs996970778; called by muse, mutect2, varscan2
- AUTS2 | c.*572A>G | 3'UTR (SNP) | VAF 31/75 reads (41%) | catalogued as rs1004602280; called by muse, mutect2, varscan2
- BCAS1 | c.*596A>C | 3'UTR (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- BLID | c.-262G>T | 5'UTR (SNP) | VAF 34/115 reads (30%) | called by muse, mutect2, varscan2
- C8orf34 | c.1549+4005G>A | Intron (SNP) | VAF 37/94 reads (39%) | called by muse, mutect2, varscan2
- CACNA2D1 | chr7:81948894 T>C | 3'Flank (SNP) | VAF 57/125 reads (46%) | called by muse, mutect2, varscan2
- CBX8 | c.*840T>C | 3'UTR (SNP) | VAF 45/115 reads (39%) | called by muse, mutect2, varscan2
- CD180 | c.-97T>G | 5'UTR (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- CDC25A | c.-451G>C | 5'UTR (SNP) | VAF 28/105 reads (27%) | catalogued as rs1354170369; called by muse, mutect2, varscan2
- CHMP1B | c.*455T>A | 3'UTR (SNP) | VAF 47/96 reads (49%) | called by muse, mutect2, varscan2
- CLVS1 | c.*533C>A | 3'UTR (SNP) | VAF 31/79 reads (39%) | called by muse, mutect2, varscan2
- CNOT7 | c.*136A>C | 3'UTR (SNP) | VAF 55/139 reads (40%) | called by muse, mutect2, varscan2
- COL5A2 | c.*1560G>T | 3'UTR (SNP) | VAF 39/96 reads (41%) | catalogued as rs565023897; called by muse, mutect2, varscan2
- CRACR2A | c.1271+1254A>G | Intron (SNP) | VAF 23/49 reads (47%) | called by muse, mutect2, varscan2
- CREB3L2 | c.*4753C>T | 3'UTR (SNP) | VAF 49/98 reads (50%) | called by muse, mutect2, varscan2
- CROCCP2 | n.2321G>C | RNA (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- CSMD2 | c.6862+1722C>T | Intron (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- CTDP1 | c.*537C>T | 3'UTR (SNP) | VAF 56/129 reads (43%) | catalogued as rs1040556936; called by muse, mutect2, varscan2
- CYB5A | c.289-1094dup | Intron (INS) | VAF 34/217 reads (16%) | called by mutect2, pindel, varscan2
- DLGAP2 | c.*4476dup | 3'UTR (INS) | VAF 35/101 reads (35%) | called by mutect2, pindel, varscan2
- DLGAP2 | c.*4702G>A | 3'UTR (SNP) | VAF 34/99 reads (34%) | called by muse, mutect2, varscan2
- DNAL4 | c.*143C>T | 3'UTR (SNP) | VAF 48/108 reads (44%) | catalogued as rs1361187741; called by muse, mutect2, varscan2
- DOCK6 | c.309-74T>G | Intron (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2
- ETV1 | chr7:13893351 G>T | 3'Flank (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- ETV1 | c.*1449A>G | 3'UTR (SNP) | VAF 33/74 reads (45%) | called by muse, mutect2, varscan2
- FAM135B | c.3638+95T>G | Intron (SNP) | VAF 36/90 reads (40%) | called by muse, mutect2, varscan2
- FAM234A | chr16:234764 del C | 5'Flank (DEL) | VAF 27/88 reads (31%) | catalogued as rs1046068718; called by mutect2, pindel, varscan2
- FBLN1 | c.1697+7822G>A | Intron (SNP) | VAF 35/81 reads (43%) | catalogued as rs995592522; called by muse, mutect2, varscan2
- GEMIN5 | c.*518A>T | 3'UTR (SNP) | VAF 21/85 reads (25%) | catalogued as rs753466973; called by muse, mutect2, varscan2
- GJB7 | c.*389_*393del | 3'UTR (DEL) | VAF 4/30 reads (13%) | called by pindel, varscan2
- GLIPR1 | c.*2098T>C | 3'UTR (SNP) | VAF 26/67 reads (39%) | called by muse, mutect2, varscan2
- GLYR1 | c.*785G>C | 3'UTR (SNP) | VAF 45/121 reads (37%) | called by muse, mutect2, varscan2
- GNA12 | c.*1066A>C | 3'UTR (SNP) | VAF 47/96 reads (49%) | called by muse, mutect2, varscan2
- GPATCH2 | c.*753T>A | 3'UTR (SNP) | VAF 37/106 reads (35%) | called by muse, mutect2, varscan2
- GRIN2A | c.*5775dup | 3'UTR (INS) | VAF 7/50 reads (14%) | catalogued as rs202247656, COSV67360326; ClinVar: uncertain significance; called by pindel, varscan2*
- GSPT1 | chr16:11872978 G>A | 3'Flank (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- HLA-DMA | c.374-13A>G | Intron (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2
- HSPB11 | c.205+148A>G | Intron (SNP) | VAF 19/40 reads (48%) | called by muse, mutect2, varscan2
- HTR3D | c.228-29C>T | Intron (SNP) | VAF 86/273 reads (32%) | called by muse, mutect2, varscan2
- IGLL5 | chr22:22899627 C>T | 3'Flank (SNP) | VAF 59/164 reads (36%) | catalogued as rs190433268; called by muse, mutect2, varscan2
- IL1RAP | c.*569T>G | 3'UTR (SNP) | VAF 35/109 reads (32%) | called by muse, mutect2, varscan2
- INPP4B | c.2643-607A>G | Intron (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- JTB | c.-404A>C | 5'UTR (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- KIF16B | c.*100T>C | 3'UTR (SNP) | VAF 88/216 reads (41%) | called by muse, mutect2, varscan2
- KRT4 | c.*509T>G | 3'UTR (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- LGSN | c.163+1188C>T | Intron (SNP) | VAF 38/106 reads (36%) | catalogued as rs756547707, COSV65728712; called by muse, mutect2, varscan2
- LINC01101 | n.25C>T | RNA (SNP) | VAF 65/185 reads (35%) | catalogued as rs944440135; called by muse, mutect2, varscan2
- LRRIQ4 | c.*61G>A | 3'UTR (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- LY6K | c.*339G>A | 3'UTR (SNP) | VAF 36/96 reads (38%) | called by muse, mutect2, varscan2
- M6PR | c.*18C>T | 3'UTR (SNP) | VAF 71/171 reads (42%) | called by muse, mutect2, varscan2
- MAP1B | c.287-14244C>T | Intron (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
- MLLT3 | c.*960G>T | 3'UTR (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- MPO | c.*66C>A | 3'UTR (SNP) | VAF 12/21 reads (57%) | called by muse, mutect2, varscan2
- MRPS30 | c.*26G>A | 3'UTR (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- NEBL | c.*5432T>C | 3'UTR (SNP) | VAF 31/80 reads (39%) | catalogued as rs1232321830; called by muse, mutect2, varscan2
- NOP10 | c.-13C>T | 5'UTR (SNP) | VAF 76/244 reads (31%) | catalogued as rs772371219; called by muse, varscan2
- OR10D1P | n.45C>T | RNA (SNP) | VAF 77/286 reads (27%) | called by muse, mutect2, varscan2
- PARPBP | c.495+951C>G | Intron (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2
- PBX2 | c.-165T>A | 5'UTR (SNP) | VAF 3/10 reads (30%) | catalogued as rs1218261386; called by muse, mutect2
- PCDH15 | c.*3634T>C | 3'UTR (SNP) | VAF 25/56 reads (45%) | called by muse, mutect2, varscan2
- PDP2 | c.*50T>G | 3'UTR (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- PIPSL | n.2123C>T | RNA (SNP) | VAF 67/213 reads (31%) | catalogued as rs1564604530; called by muse, mutect2, varscan2
- PRKCB | c.1864-876G>A | Intron (SNP) | VAF 32/117 reads (27%) | called by muse, mutect2, varscan2
- PSMA6 | c.409+69T>C | Intron (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- PTPN12 | c.382-148A>C | Intron (SNP) | VAF 14/61 reads (23%) | called by muse, mutect2, varscan2
- RAB34 | c.-411C>A | 5'UTR (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- RAB34 | c.-412C>A | 5'UTR (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- RBFOX1 | c.318+52T>A | Intron (SNP) | VAF 133/332 reads (40%) | called by muse, mutect2, varscan2
- RBM24 | c.*1343del | 3'UTR (DEL) | VAF 22/58 reads (38%) | catalogued as rs910817083; called by mutect2, varscan2
- RBM33 | c.*2785A>G | 3'UTR (SNP) | VAF 34/92 reads (37%) | catalogued as rs1277376228; called by muse, mutect2, varscan2
- RICTOR | c.*2195T>C | 3'UTR (SNP) | VAF 31/81 reads (38%) | called by muse, mutect2, varscan2
- RN7SL860P | chr19:22603465 del G | 3'Flank (DEL) | VAF 51/336 reads (15%) | called by mutect2, pindel, varscan2
- ROPN1 | c.*12T>C | 3'UTR (SNP) | VAF 102/602 reads (17%) | called by muse, mutect2, varscan2
- RRP15 | c.*1924A>G | 3'UTR (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.*1366T>G | 3'UTR (SNP) | VAF 23/43 reads (53%) | called by muse, mutect2, varscan2
- SEMA3D | c.*2162G>T | 3'UTR (SNP) | VAF 33/62 reads (53%) | called by muse, mutect2, varscan2
- SLC36A1 | c.*161G>A | 3'UTR (SNP) | VAF 45/154 reads (29%) | called by muse, mutect2, varscan2
- SLC6A15 | c.756+1669A>G | Intron (SNP) | VAF 36/103 reads (35%) | called by muse, mutect2, varscan2
- SLC7A10 | c.912+18C>T | Intron (SNP) | VAF 16/198 reads (8%) | catalogued as rs993810768, COSV53503871; called by muse, mutect2
- SMAD9 | c.*1586T>C | 3'UTR (SNP) | VAF 32/73 reads (44%) | called by muse, mutect2, varscan2
- SPRED1 | c.*788T>A | 3'UTR (SNP) | VAF 26/105 reads (25%) | catalogued as COSV54437286; called by muse, varscan2
- SREK1IP1 | c.*2223A>C | 3'UTR (SNP) | VAF 43/144 reads (30%) | called by muse, mutect2, varscan2
- TEKT4 | c.-52G>A | 5'UTR (SNP) | VAF 28/68 reads (41%) | catalogued as rs1394518690; called by muse, mutect2
- TSLP | chr5:111071494 T>C | 5'Flank (SNP) | VAF 128/450 reads (28%) | called by muse, mutect2, varscan2
- TTC9C | c.-101C>T | 5'UTR (SNP) | VAF 171/575 reads (30%) | called by muse, mutect2, varscan2
- TXNIP | c.*1167A>G | 3'UTR (SNP) | VAF 56/117 reads (48%) | called by muse, mutect2, varscan2
- UBE2D3 | chr4:102797126 T>C | 3'Flank (SNP) | VAF 145/347 reads (42%) | catalogued as rs748404192; called by muse, mutect2, varscan2
- UBXN4 | c.-46C>T | 5'UTR (SNP) | VAF 19/137 reads (14%) | catalogued as rs1260825373; called by muse, mutect2, varscan2
- VPS39 | chr15:42159368 C>T | 3'Flank (SNP) | VAF 58/196 reads (30%) | called by muse, mutect2, varscan2
- WDR70 | c.*559A>G | 3'UTR (SNP) | VAF 45/123 reads (37%) | catalogued as rs1334715016; called by muse, mutect2, varscan2
- ZC3H12C | c.*1934A>G | 3'UTR (SNP) | VAF 23/123 reads (19%) | called by muse, mutect2, varscan2
- ZMYND8 | c.-46-1974T>C | Intron (SNP) | VAF 100/230 reads (43%) | called by muse, mutect2, varscan2
- ZNF211 | chr19:57642783 del T | 3'Flank (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel
- ZNF486 | c.-100G>C | 5'UTR (SNP) | VAF 20/161 reads (12%) | called by muse, mutect2, varscan2
- ZNF516 | chr18:76495535 A>T | 5'Flank (SNP) | VAF 64/235 reads (27%) | called by muse, mutect2, varscan2
